Somatic mutation profile of tumor specimen TCGA-32-1982-01A (aliquot TCGA-32-1982-01A-01W-0837-08) from TCGA case TCGA-32-1982, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.0 years (27,764 days).
Specimen TCGA-32-1982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ada864d1-82e2-46da-9db8-339aa1c830de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-1982-10A (Blood Derived Normal), aliquot TCGA-32-1982-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4073a90-f543-4905-a94a-1186af54ab91

The open-access MAF lists 117 somatic variants for this specimen: 82 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 33, Frame Shift Ins 7, Nonsense Mutation 5, Frame Shift Del 3, RNA 2, Splice Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 2039/2602 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LDLRAP1 | c.603dup p.S202Lfs*19 | Frame Shift Ins (INS) | VAF 12/104 reads (12%) | catalogued as rs781585299; ClinVar: pathogenic; called by pindel, varscan2
- AHNAK2 | c.9812A>T p.Q3271L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777007026, COSV60920263; called by muse, varscan2
- AL592490.1 | c.2800G>T p.G934* | Nonsense Mutation (SNP) | VAF 16/144 reads (11%) | catalogued as COSV101308266; called by muse, mutect2, varscan2
- AMMECR1L | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 80/357 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs773853713, COSV55762122; called by muse, mutect2, varscan2
- ANKRA2 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs553343150, COSV57142090; called by muse, mutect2, varscan2
- ANO2 | c.1852C>T p.R618C (on ENST00000356134 / NM_001278597.3; = p.R622C on NM_001278596.3) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs768041346, COSV59038711; called by muse, mutect2, varscan2
- APOB | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 78/313 reads (25%) | catalogued as CD076733, COSV51957587; called by muse, mutect2, varscan2
- ATP6V0D1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV52100299; called by muse, mutect2, varscan2
- BACH1 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776374291, COSV99727870, COSV99728216; called by muse, mutect2, varscan2
- CD8B | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 64/534 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs375735227, COSV58925557; called by muse, varscan2
- CHAT | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs116097791, COSV60333222; called by muse, mutect2, varscan2
- COL6A2 | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.801); catalogued as rs541785316, COSV56018266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL2 | c.2174T>A p.L725Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66081631; called by muse, mutect2, varscan2
- DKC1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV65730389; called by muse, mutect2, varscan2
- DNAH2 | c.2668G>A p.A890T | Missense Mutation (SNP) | VAF 107/501 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs112194246, COSV66728896, COSV66730170; called by muse, mutect2, varscan2
- EEF1A1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100303411, COSV58550679; called by muse, mutect2, varscan2
- ENPP2 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs767465276, COSV50010797; called by muse, varscan2
- FLCN | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447526883; called by muse, mutect2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 16/54 reads (30%) | catalogued as rs749150409; called by mutect2, varscan2
- GPRC6A | c.146_148del p.L49del | In Frame Del (DEL) | VAF 20/116 reads (17%) | catalogued as rs1463817401; called by pindel, varscan2
- HBS1L | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV63203030; called by muse, mutect2, varscan2
- IFT22 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 28/452 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59527733; called by muse, mutect2
- IL12RB1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs1259138980, COSV59097101; called by muse, mutect2, varscan2
- IL4R | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs780006435, COSV50189985; called by muse, mutect2, varscan2
- JPH1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs777573780, COSV60608760; called by muse, mutect2
- JPH2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773609773, COSV65906167; called by muse, mutect2, varscan2
- KLKB1 | c.960G>T p.E320D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV52995221; called by muse, mutect2, varscan2
- LMTK2 | c.3072dup p.D1025Rfs*2 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | catalogued as rs771256120; called by mutect2, pindel, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 36/174 reads (21%) | catalogued as rs746133895; called by mutect2, varscan2
- LRRC18 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs138127999; called by muse, mutect2, varscan2
- LRRIQ1 | c.2695G>T p.G899* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV67840596; called by muse, mutect2
- MAGEA6 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61449600; called by muse, mutect2, varscan2
- MAP3K4 | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV62340056; called by muse, varscan2
- MAP3K4 | c.3967G>A p.D1323N | Missense Mutation (SNP) | VAF 66/356 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV62340069; called by muse, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 17/83 reads (20%) | catalogued as rs777328830; called by mutect2, varscan2
- MDGA1 | c.2563C>T p.R855W | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1462163414; called by muse, mutect2
- MFAP1 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 124/632 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); catalogued as rs1165156337, COSV51042083; called by muse, mutect2, varscan2
- MPPE1 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.086); catalogued as rs138699115; called by muse, mutect2, varscan2
- MTMR11 | c.1789A>G p.I597V (on ENST00000439741 / NM_001145862.2; = p.I525V on NM_181873.3) | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375433690; called by muse, mutect2, varscan2
- OR2T33 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 106/541 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as COSV58818467; called by muse, mutect2, varscan2
- OR5T3 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV57383031; called by muse, mutect2, varscan2
- PCARE | c.2650G>A p.A884T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as rs987171349, COSV59055152; called by muse, mutect2, varscan2
- PCDHA1 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.223); catalogued as rs1554118074, COSV65374227; called by muse, mutect2, varscan2
- PCDHA8 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65338768; called by muse, mutect2, varscan2
- PCDHGB4 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1388057704, COSV53910946; called by muse, mutect2, varscan2
- PDGFRA | c.1552G>T p.A518S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as rs372546959; called by muse, mutect2, varscan2
- PRKG2 | c.989A>G p.K330R | Missense Mutation (SNP) | VAF 132/149 reads (89%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV52333823; called by muse, mutect2, varscan2
- PTPN20 | c.1174C>T p.R392C (on ENST00000374339 / NM_001042357.4; = p.T208M on NM_015605.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/344 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1187850829; called by muse, mutect2, varscan2
- RPA4 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs766197285, COSV61266336; called by muse, mutect2, varscan2
- RYR3 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 205/417 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.453); catalogued as rs764639699, COSV66811601; called by muse, mutect2, varscan2
- SEC14L5 | c.1230C>A p.D410E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.21); catalogued as COSV52042820; called by muse, mutect2, varscan2
- SETD6 | c.887T>C p.M296T (on ENST00000219315 / NM_001160305.4; = p.M272T on NM_024860.3) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs773531736, COSV50752670; called by muse, mutect2, varscan2
- SMC1A | c.914C>A p.T305N | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV59132450; called by muse, mutect2, varscan2
- SULT1B1 | c.294G>C p.E98D | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100150486, COSV60209874; called by muse, mutect2, varscan2
- SYNE1 | c.529C>T p.Q177* (on ENST00000367255 / NM_182961.4; = p.Q184* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 42/257 reads (16%) | catalogued as COSV54929870; called by muse, mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 58/377 reads (15%) | catalogued as rs782753958; called by mutect2, varscan2
- TSNARE1 | c.1516A>G p.I506V | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56185642; called by muse, mutect2, varscan2
- TTN | c.54614A>C p.N18205T (on ENST00000591111; = p.N10781T on NM_003319.4) | Missense Mutation (SNP) | VAF 190/354 reads (54%) | PolyPhen possibly damaging (0.496); catalogued as COSV60416191; called by muse, mutect2, varscan2
- TTN | c.45334G>A p.G15112R (on ENST00000591111; = p.G7688R on NM_003319.4) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | PolyPhen probably damaging (1); catalogued as COSV60416225; called by muse, mutect2, varscan2
- VWCE | c.1466dup p.Q490Tfs*30 | Frame Shift Ins (INS) | VAF 13/98 reads (13%) | catalogued as rs753714493; called by mutect2, varscan2
- ZFP42 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs535489031, COSV58816365; called by muse, mutect2, varscan2
- ZFP42 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs200711766, COSV58816789; called by muse, mutect2, varscan2
- ZNF37A | c.237G>T p.L79= | Splice Region (SNP) | VAF 18/36 reads (50%) | catalogued as COSV61076057; called by muse, mutect2, varscan2
- ZNF624 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as rs776543723, COSV60941828; called by muse, mutect2, varscan2
- ZSCAN9 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 217/605 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs762408614, COSV52851195; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2315C>A p.A772D | Missense Mutation (SNP) | VAF 40/592 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- BRS3 | c.230C>A p.S77Y | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CAMTA2 | c.1517del p.F506Sfs*87 | Frame Shift Del (DEL) | VAF 506/1045 reads (48%) | called by mutect2, pindel, varscan2
- CDKL5 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 107/371 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHD8 | c.6764_6768del p.I2255Rfs*2 (on ENST00000646647 / NM_001170629.2; = p.I1976Rfs*2 on NM_020920.4) | Frame Shift Del (DEL) | VAF 42/205 reads (20%) | called by pindel, varscan2
- FCGR3A | c.62-1G>T p.X21_splice | Splice Site (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- GARRE1 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HMGCS1 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- MAGEF1 | c.848G>A p.R283K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MLH3 | c.2813C>T p.S938L | Missense Mutation (SNP) | VAF 36/536 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- NAP1L3 | c.1334C>A p.P445H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RALBP1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SMG1 | c.3649_3650del p.T1217Qfs*2 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | called by mutect2, varscan2
- VPS13B | c.11794C>T p.Q3932* | Nonsense Mutation (SNP) | VAF 20/466 reads (4%) | called by muse, mutect2
- WAS | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZGPAT | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- ABCA4 | c.6015C>A p.T2005= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- ADAM28 | c.792G>A p.K264= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs1254782938, COSV56106773; called by muse, mutect2, varscan2
- ADAMTS10 | c.456C>T p.D152= | Silent (SNP) | VAF 14/193 reads (7%) | catalogued as rs371629978; called by muse, mutect2
- ATP5PB | c.714G>A p.K238= | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- CCDC134 | c.441C>T p.C147= | Silent (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
- CDH1 | c.1773C>T p.N591= | Silent (SNP) | VAF 68/493 reads (14%) | catalogued as rs373719554, COSV55735575; ClinVar: benign / likely benign; called by muse, varscan2
- CFAP47 | c.4797C>T p.L1599= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV57977373; called by muse, mutect2, varscan2
- CHDH | c.774C>T p.A258= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs199770725, COSV59460538; called by muse, mutect2, varscan2
- CRTAM | c.108A>C p.L36= | Silent (SNP) | VAF 25/122 reads (20%) | called by mutect2, varscan2
- DLX4 | c.465C>T p.G155= (on ENST00000240306 / NM_138281.3; = p.G83= on NM_001934.3) | Silent (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- DNAH7 | c.9474G>A p.S3158= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs375959193; called by muse, varscan2
- EIF4E1B | c.150G>T p.R50= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- EPB41L4B | c.1107G>A p.T369= | Silent (SNP) | VAF 70/290 reads (24%) | catalogued as rs377599387; called by muse, varscan2
- GRIN1 | c.300C>T p.D100= | Silent (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- LRRK2 | c.2931G>A p.L977= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as rs1565722900, COSV54175437; called by muse, mutect2, varscan2
- MAST1 | c.624C>T p.S208= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs1234765994; called by muse, mutect2, varscan2
- MID2 | c.507G>A p.T169= | Silent (SNP) | VAF 251/372 reads (67%) | catalogued as rs376601333, COSV53310350; called by muse, varscan2
- MUC16 | c.28575C>A p.T9525= | Silent (SNP) | VAF 41/214 reads (19%) | catalogued as rs760191219, COSV67461953; called by muse, mutect2, varscan2
- MUC16 | c.9909G>A p.G3303= | Silent (SNP) | VAF 16/594 reads (3%) | catalogued as rs943899254; called by muse, mutect2
- MYH6 | c.1398C>T p.F466= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs745448722, COSV62448949; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP13 | c.2004C>T p.D668= | Silent (SNP) | VAF 246/717 reads (34%) | catalogued as rs140606375; called by muse, mutect2, varscan2
- NUCB2 | c.894G>A p.R298= | Silent (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- PCDH19 | c.738C>T p.S246= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as COSV55270755; called by muse, mutect2, varscan2
- PCDHB15 | c.1389C>T p.N463= | Silent (SNP) | VAF 40/294 reads (14%) | called by muse, mutect2
- PRPF4 | c.879C>T p.V293= (on ENST00000374198 / NM_001322267.2; = p.V294= on NM_004697.5) | Silent (SNP) | VAF 1207/2018 reads (60%) | called by muse, mutect2, varscan2
- PSD | c.2064C>T p.G688= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1386694692; called by muse, mutect2, varscan2
- RAD51C | c.234A>G p.T78= | Silent (SNP) | VAF 53/97 reads (55%) | catalogued as rs730881929, COSV53628592; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SCN10A | c.2757C>A p.V919= | Silent (SNP) | VAF 74/537 reads (14%) | catalogued as rs200993949, COSV101479505; called by muse, mutect2, varscan2
- TAF1 | c.4233C>T p.R1411= (on ENST00000373790 / NM_138923.4; = p.R1432= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 98/357 reads (27%) | catalogued as rs751992377, COSV52128374; ClinVar: benign; called by muse, mutect2, varscan2
- TPO | c.2664C>T p.G888= | Silent (SNP) | VAF 159/216 reads (74%) | catalogued as rs753589249, COSV100221098, COSV61105294; called by muse, mutect2, varscan2
- TRAJ38 | c.24G>A p.K8= | Silent (SNP) | VAF 39/742 reads (5%) | catalogued as rs1566731035; called by muse, mutect2
- USH1C | c.1344C>T p.I448= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1353888178; called by muse, mutect2, varscan2
- WDR93 | c.1632C>A p.G544= | Silent (SNP) | VAF 46/739 reads (6%) | called by muse, mutect2
- CLCA3P | n.162C>A | RNA (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- SNORD116-24 | n.77C>T | RNA (SNP) | VAF 315/621 reads (51%) | catalogued as rs769187796; called by muse, mutect2, varscan2
